FM case AD12671 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Ureter.
https://portal.gdc.cancer.gov/cases/78796a4d-841c-4f6f-8889-0a2fd28986a4

Male, 65.6 years: Urothelial carcinoma, NOS (ICD-O-3 8120/3) of the ureter; metastasis biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
